Somatic mutation profile of tumor specimen TCGA-2G-AAKO-05A (aliquot TCGA-2G-AAKO-05A-11D-A42Y-10) from TCGA case TCGA-2G-AAKO, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AAKO-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8628be2b-cf2a-42ab-9b5f-5a67d35ac0fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAKO-10A (Blood Derived Normal), aliquot TCGA-2G-AAKO-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/900d1888-6859-448a-a85c-bf0adb28789a

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, RNA 1, 5'UTR 1, Nonsense Mutation 1, Silent 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 14/182 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ERICH1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs1429066014; called by muse, mutect2, varscan2
- FAM104A | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.49); catalogued as COSV52147385; called by muse, mutect2
- SMC3 | c.2908G>C p.E970Q | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as COSV100699834; called by muse, mutect2
- ARMC3 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CYP19A1 | c.1216T>C p.F406L | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2
- DENND5B | c.650C>G p.S217* | Nonsense Mutation (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- GLYATL3 | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KDM5A | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- UBE2M | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZMYM4 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2
- PRORP | c.609C>G p.A203= | Silent (SNP) | VAF 11/136 reads (8%) | called by muse, mutect2
- MORF4 | n.777G>A | RNA (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- NT5C3A | c.-9G>C | 5'UTR (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
